Somatic mutation profile of tumor specimen MP2PRT-PASYAI-TMP1-A (aliquot MP2PRT-PASYAI-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASYAI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,350 days).
Specimen MP2PRT-PASYAI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf33fa73-f7db-4a75-a4ad-c00de24bd156.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYAI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYAI-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61afe0dc-2ca3-48aa-870d-113f9f9c0765

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 17, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 41/609 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs777892697; called by muse, mutect2
- BSN | c.2497C>T p.R833W | Missense Mutation (SNP) | VAF 122/558 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs762515353; called by muse, mutect2, varscan2
- CPSF3 | c.1903C>A p.L635I | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV53008769, COSV99432626; called by muse, mutect2, varscan2
- FRY | c.7027C>T p.R2343W | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1452957961, COSV100968919; called by muse, mutect2, varscan2
- GRIA1 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 78/546 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs763355837, COSV53615269; called by muse, mutect2, varscan2
- KRT4 | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 15/458 reads (3%) | catalogued as rs1284159580, COSV104395655, COSV53405642; called by muse, mutect2
- LPA | c.3136G>C p.E1046Q | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); catalogued as COSV60299501; called by muse, mutect2
- OBSCN | c.19672G>A p.V6558M | Missense Mutation (SNP) | VAF 34/647 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs376202409; called by muse, mutect2
- PHEX | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 15/465 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1167621943; called by muse, mutect2
- PPHLN1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 95/541 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs543940866, COSV56728124; called by muse, mutect2, varscan2
- STOX2 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 82/427 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs1246197618, COSV57849084; called by muse, varscan2
- RBM27 | c.3089T>G p.V1030G | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2
- RIMBP2 | c.1736C>A p.A579D | Missense Mutation (SNP) | VAF 40/749 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2
- SFT2D3 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 196/1074 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SKOR1 | c.2297G>C p.G766A | Missense Mutation (SNP) | VAF 94/491 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- THOP1 | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 21/696 reads (3%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- TRPM3 | c.3917A>G p.N1306S (on ENST00000357533 / NM_001366142.2; = p.N1161S on NM_020952.6) | Missense Mutation (SNP) | VAF 25/570 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.068); called by muse, mutect2
- VLDLR | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 74/527 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C7 | c.1821A>G p.G607= | Silent (SNP) | VAF 26/479 reads (5%) | called by muse, mutect2
- LOXHD1 | c.5934C>T p.D1978= (on ENST00000642948; = p.D1916= on NM_144612.7) | Silent (SNP) | VAF 163/422 reads (39%) | catalogued as rs769356212, COSV56063030; ClinVar: likely benign; called by muse, varscan2
- PCDHB10 | c.2172G>T p.V724= | Silent (SNP) | VAF 90/602 reads (15%) | called by muse, mutect2, varscan2
- SHROOM2 | c.1182C>T p.D394= | Silent (SNP) | VAF 54/1036 reads (5%) | catalogued as rs377422277, COSV66606796; called by muse, mutect2
- TRIM72 | c.612C>T p.A204= | Silent (SNP) | VAF 48/745 reads (6%) | called by muse, mutect2
